Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4R-01A (Primary Tumor).

Histopathology Histopathology

Specimen Comments

SPECIMEN

Bladder and prostate.

2 - Right obturator.

3 - Right external iliac.

4 - Left distal ureteric margin.

5 - Right distal ureteric margin.

CLINICAL DETAILS

Bladder cancer. Clinically involved obturator nodes right, cystectomy & right lymphadenectomy.

MACROSCOPY

1 - Cysto-prostatectomy specimen measuring 125 mm supero-inferiorly x 110 mm medio-lateral x 65 mm antero-posteriorly. The prostate measures 30 mm superior to inferior and 45 mm medial to lateral. On sectioning there is a tumour situated on the right side. The tumour abuts the perivesical fat and measures 20 mm x 6 mm. The background mucosa appears haemorrhagic and possibly abnormal.

The prostate shows nodularity with the most prominent nodule extending towards bladder urethral orifice. The seminal vesicles appear spared by tumour, as well as the prostate.

2 - A piece of fibrous tissue measuring 55 x 38 x 22 mm. Sectioning shows 2 lymph nodes, the larger 40 mm in maximum dimension. Both nodes appear infiltrated by tumour.

3 - A piece of fibrofatty tissue 48 x 20 x 8 mm. 4 lymph nodes are identified, the largest 8 mm in maximum dimension.

4 - A piece of ureter 7 mm long. All embedded.

5 - A piece of ureter 10 mm long. All embedded.

MICROSCOPY

Specimens 1, 2, 3, 4 & 5

The sections of the bladder show grade 3 transitional cell carcinoma that extends into the perivesical fat. Perineural and vascular are present. The ureteric, urethral and soft tissue margins are clear. The prostate shows areas of granulomatous inflammation which would be in keeping with BCG treatment.

The background urothelium is reactive but no carcinoma in situ is identified.

6 lymph nodes have been identified. 2 right obturator nodes contain metastatic tumour while 4 right external iliac nodes are negative.

SUMMARY

Cystoprostatectomy with right obturator and external iliac nodes - completely excised grade 3 transitional cell carcinoma, with 2 positive right obturator lymph nodes; G3, pT3a, N2, Mx

Ref:

Pathologists -

CE ICD O-3
Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site: Bladder NOS C679
JW 4/30/14

(BCL completed prior.)

Source: NCI Genomic Data Commons file b7b62570-ebb0-4da8-b2b5-331464ce01e6 (TCGA-ZF-AA4R.6E9D0F98-3697-46E7-96E6-1CDAAE63DFC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).